Gene-level copy-number profile of tumor specimen TCGA-NC-A5HF-01A from TCGA case TCGA-NC-A5HF, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 74.0 years (27,038 days).
Specimen TCGA-NC-A5HF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.5fd0a7d8-bd3e-4cc7-8c3c-02a3487ce771.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NC-A5HF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/db4b5b11-0716-4df9-9dfe-1ec2170587de

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 72; copy number 1: 2; copy number 2: 17,803; copy number 4: 36,873; copy number 5: 1,487; copy number 6: 2,522; copy number 8: 300; copy number 9: 153; copy number 11: 176; copy number 12: 112; copy number 13: 54; copy number 14: 55; copy number 15: 6; copy number 17: 5; copy number 19: 67; copy number 20: 32; copy number 33: 20; copy number 36: 34; copy number 64: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NC-A5HF-01A-11D-A26L-01): tumor purity 0.75, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 72 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:17,134,982–17,797,124, 4 genes (within-gene range 0–2): CNTLN, SAMM50P1, SH3GL2, PABPC1P11.
- chr9:19,926,094–22,214,672, 68 genes (within-gene range 0–4) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 751 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:13,690,331–45,895,970, 457 genes, copy number 9–14 (within-gene range 8–14) (broad region; genes not listed).
- chr5:52,282,567–52,282,859, 1 gene, copy number 9: RPS17P11.
- chr5:52,989,340–53,487,134, 9 genes, copy number 9 (within-gene range 4–9): ITGA2, AC008966.3, AC008966.2, MOCS2, AC008966.1, AC026477.1, AC027329.1, AC108114.1, FST.
- chr5:53,883,942–54,310,582, 1 gene, copy number 9 (within-gene range 2–9): ARL15.
- chr5:54,075,518–55,552,554, 36 genes, copy number 9: AC016601.1, AC008873.1, LINC01033, RPL37P25, HSPB3, SNX18, AC016583.1, AC016583.2, CSPG4BP, AC112198.1, AC112198.3, AC112198.2, ESM1, AC034238.1, GZMK, Y_RNA, AC034238.3, AC034238.2, GZMAP1, GZMA, CDC20B, GPX8, MIR449A, MIR449B, MIR449C, MCIDAS, CCNO, AC026704.1, DHX29, MTREX, AC020728.1, PLPP1, AC010480.1, MIR5687, RNF138P1, AK4P2.
- chr5:95,962,001–96,631,085, 1 gene, copy number 9 (within-gene range 2–9): AC104123.1.
- chr5:96,213,346–97,057,358, 14 genes, copy number 9: AC099509.1, AC099509.2, PCSK1, CAST, AC020900.1, ERAP1, AC008906.1, AC008906.2, AC009126.1, ERAP2, LNPEP, AC008850.1, Y_RNA, SETP22.
- chr5:97,091,867–97,142,753, 1 gene, copy number 9 (within-gene range 2–9): LIX1.
- chr11:32,829,927–33,892,076, 30 genes, copy number 12: PRRG4, QSER1, Y_RNA, DEPDC7, TCP11L1, PIGCP1, LINC00294, CSTF3, CSTF3-DT, Y_RNA, RPL29P23, Y_RNA, AL136126.1, HIPK3, KIAA1549L, AL137161.1, AL133399.1, AL049629.1, C11orf91, AL049629.2, CD59, FBXO3, FBXO3-DT, AC113192.3, AC113192.2, LINC02722, AC113192.1, LINC02721, LMO2, AC132216.1.
- chr12:15,911,302–16,992,083, 13 genes, copy number 19 (within-gene range 2–19): DERA, EGLN3P1, SLC15A5, MGST1, SUPT16HP1, AC007528.1, AC007552.1, LMO3, AC007552.2, AC007529.2, AC007529.1, SKP1P2, EEF1A1P16.
- chr12:18,493,051–27,094,223, 134 genes, copy number 15–64 (broad region; genes not listed).
- chr12:29,658,376–31,811,190, 54 genes, copy number 19: RPL21P99, AC023511.3, AC023511.2, AC023511.1, LINC02386, AC078776.2, RNA5SP356, AC078776.1, AC026371.1, IPO8, AC012673.1, CAPRIN2, AC010198.1, LINC00941, AC010198.2, PPIAP44, TSPAN11, AC008013.1, AC008013.2, DDX11-AS1, DDX11, SNORA75, AC008013.3, AC024940.1, AC024940.4, AC024940.2, MREGP1, AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
